Gene-level copy-number profile of tumor specimen TCGA-63-7021-01A from TCGA case TCGA-63-7021, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-7021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e4dc76f7-722f-47dc-9847-b76ab2df0c09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-7021-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a914017e-9233-43ee-892e-db03a4de1952

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 12,257; copy number 2: 39,657; copy number 3: 6,406; copy number 4: 680; copy number 5: 357; copy number 6: 424; copy number 7: 13; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-7021-01A-11D-1943-01): tumor purity 0.26, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,455,740, 18 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 796 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,773,145–198,222,513, 487 genes, copy number 5–6 (broad region; genes not listed).
- chr4:48,135,783–48,269,838, 1 gene, copy number 7 (within-gene range 4–7): TEC.
- chr4:48,341,529–49,062,081, 12 genes, copy number 7: SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr8:131,308,545–145,066,685, 287 genes, copy number 5 (broad region; genes not listed).
- chr10:92,451,684–92,710,608, 7 genes, copy number 5 (within-gene range 1–5): IDE, KIF11, RPL11P4, RN7SL644P, EIF2S2P3, HHEX, Y_RNA.
- chr10:93,591,687–93,666,010, 2 genes, copy number 10: RBP4, PDE6C.

Autosomal genes at a single copy (total copy number 1): 9,842. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
